TARGET case TARGET-40-NAAGJP — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6bb0243a-600b-5d67-bfd1-d83552ae88ce

Demographics
Sex at birth: female; Race: asian; Age at index: 29 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 30.0 years (10,941 days); Year of diagnosis: 2005; Metastasis at diagnosis: No Metastasis; Days to last follow up: 3,443 days (9.4 years).
   Pathology details: Necrosis percent: 40.

Follow-up (2 entries)
- Days to follow up: 3,272 days (9.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,272.
- Days to follow up: 3,443 days (9.4 years); Year of follow up: 2014.

Biospecimens (3 samples)
- Sample TARGET-40-NAAGJP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAGJP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-40-NAAGJP-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGJP-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 81
- % Normal: Top from Biopsy: 12
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 7

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3443
- Protocol: Other osteosarcoma
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Histologic response: Stage 1/2 (0-90 % necrosis)
